Somatic mutation profile of tumor specimen HCM-CSHL-0143-C20-01A (aliquot HCM-CSHL-0143-C20-01A-11D-A77E-36) from HCMI case HCM-CSHL-0143-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-CSHL-0143-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecc8794d-bd04-422f-88b1-9dea708a2ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0143-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0143-C20-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f184d1fc-98d7-4c06-83fc-09904aadf219

The open-access MAF lists 141 somatic variants for this specimen: 99 protein-altering or splice-affecting, 30 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 30, Nonsense Mutation 5, 5'UTR 4, Intron 3, Splice Region 2, In Frame Del 2, 5'Flank 2, Frame Shift Del 2, Splice Site 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 108/343 reads (31%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 123/334 reads (37%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- CDH1 | c.1565+2dup p.X522_splice | Splice Site (INS) | VAF 128/400 reads (32%) | catalogued as rs1555516200, CI085159, CI146398; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 86/275 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 198/548 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 139/374 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MC4R | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs549442687, CM061841, COSV55352780; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OTOGL | c.3760del p.Y1254Ifs*3 (on ENST00000547103; = p.Y1245Ifs*3 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | catalogued as rs1064795124; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 6/58 reads (10%) | hotspot (GDC flag); called by pindel, varscan2
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- ABCB1 | c.2688C>T p.I896= | Splice Region (SNP) | VAF 49/532 reads (9%) | catalogued as rs532094830, COSV99714822; called by muse, mutect2
- ABCC2 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs750565571; called by muse, mutect2
- BLVRB | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs762544157; called by muse, mutect2, varscan2
- CACNA1H | c.6652C>T p.R2218C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761083620, COSV52353706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD1E | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63769908; called by muse, mutect2, varscan2
- CDH1 | c.2431A>C p.I811L | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55741411; called by muse, mutect2, varscan2
- CEMIP | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 305/761 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV55000517; called by muse, mutect2, varscan2
- CHTF18 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781134628; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- CRYBG1 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226140016; called by muse, mutect2, varscan2
- CSGALNACT1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 75/605 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs756494914; called by muse, mutect2, varscan2
- DDX54 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 147/360 reads (41%) | catalogued as rs767686054; called by muse, mutect2, varscan2
- DLC1 | c.3170C>T p.A1057V (on ENST00000276297 / NM_001348081.2; = p.A620V on NM_006094.5) | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV52298290; called by muse, mutect2, varscan2
- DUSP21 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 145/413 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as rs769190462, COSV59133879; called by muse, mutect2, varscan2
- DUSP9 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 225/504 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV61438275; called by muse, mutect2, varscan2
- EPHA7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.722); catalogued as rs1251015381, COSV100992487; called by muse, mutect2
- FAM184A | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs766274838, COSV58851824; called by muse, mutect2, varscan2
- FAM81B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as rs746583579, COSV51982028; called by muse, mutect2, varscan2
- FRMPD1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780248862, COSV66703083; called by muse, mutect2, varscan2
- FRMPD3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751103095, COSV52193920; called by muse, mutect2
- FTHL17 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs758861598; called by muse, mutect2, varscan2
- GCM1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762898529; called by muse, mutect2, varscan2
- GHR | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 155/366 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs749019259; called by muse, mutect2, varscan2
- GP5 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs201416119; called by muse, mutect2, varscan2
- GRIA1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 185/446 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1302659705; called by muse, mutect2, varscan2
- GRIK3 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs765867454; called by muse, mutect2, varscan2
- HDAC7 | c.1111C>T p.P371S (on ENST00000427332; = p.P410S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV99317146; called by muse, mutect2, varscan2
- KATNIP | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 155/352 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757390970, COSV55172619; called by muse, mutect2, varscan2
- KCNC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 167/384 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- KCNK3 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1188597842; called by muse, mutect2, varscan2
- KLHL2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 177/496 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV56976838; called by muse, mutect2, varscan2
- LPL | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs144466625, CM1410362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRWD1 | c.1562T>A p.I521N | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209573737; called by muse, mutect2, varscan2
- MGAM2 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229672108; called by muse, mutect2, varscan2
- MICU3 | c.1411T>C p.S471P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV58846244; called by muse, mutect2, varscan2
- MSRB1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 241/646 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs376757252; called by muse, mutect2, varscan2
- MYH14 | c.5873G>A p.R1958H | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs764476849; called by muse, mutect2
- NLGN1 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as COSV64331258; called by muse, mutect2, varscan2
- NLGN4X | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 36/794 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs776811140, COSV52019334; called by muse, mutect2
- NPBWR1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 206/669 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs567536404, COSV100488325; called by muse, mutect2, varscan2
- NPC1L1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 307/802 reads (38%) | catalogued as rs565991480, CM1412454, COSV56923952; called by muse, mutect2, varscan2
- ONECUT2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 14/459 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385109761; called by muse, mutect2
- PADI2 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs367804119, COSV99070347; called by muse, mutect2
- PIGG | c.1997G>A p.R666Q (on ENST00000453061 / NM_001127178.3; = p.R658Q on NM_017733.4) | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1162996177; called by muse, mutect2, varscan2
- PLCL1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559098498, COSV70821877; called by muse, mutect2, varscan2
- PLG | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 309/736 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767909495; called by muse, mutect2, varscan2
- PLOD2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 197/531 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs766155244; called by muse, mutect2, varscan2
- PRDM5 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 228/688 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs371714829; called by muse, varscan2
- PURG | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767466974, COSV53296113; called by muse, mutect2, varscan2
- RASA3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1036576299; called by muse, mutect2, varscan2
- RASD2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53352886, COSV53353647; called by muse, mutect2, varscan2
- SETBP1 | c.3818C>T p.T1273M | Missense Mutation (SNP) | VAF 216/319 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs958733748; called by muse, mutect2, varscan2
- SLC27A6 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs144856578; called by muse, mutect2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2
- SMAD2 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV50994183; called by muse, mutect2, varscan2
- SMAD4 | c.1619T>A p.L540H | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61684798, COSV61685874, COSV61693863; called by muse, varscan2
- STOX2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.972); catalogued as rs749643820; called by muse, mutect2, varscan2
- TANC2 | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs756059493, COSV104432167, COSV67339431; called by muse, mutect2
- TNPO1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 165/470 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370903533; called by muse, mutect2, varscan2
- ZBTB10 | c.1133A>C p.H378P | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100990164; called by muse, mutect2, varscan2
- ZNF320 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1177697365; called by muse, mutect2
- ZNF398 | c.931C>T p.R311C (on ENST00000475153 / NM_170686.3; = p.R140C on NM_020781.4) | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199601006, COSV60066317; called by muse, mutect2, varscan2
- ZNF536 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs767972699, COSV62825955; called by muse, mutect2, varscan2
- ZNF721 | c.822T>A p.F274L (on ENST00000338977; = p.F286L on NM_133474.4) | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59089742; called by muse, mutect2, varscan2
- ANOS1 | c.1443G>T p.M481I | Missense Mutation (SNP) | VAF 164/498 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf94 | c.976G>A p.A326T (on ENST00000488417 / NM_001134734.2; = p.A136T on NM_032884.5) | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC87 | c.2027A>G p.K676R | Missense Mutation (SNP) | VAF 176/451 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- COL24A1 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.579); called by muse, mutect2
- COL6A3 | c.8338A>T p.I2780F | Missense Mutation (SNP) | VAF 75/758 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FBXO11 | c.2556A>G p.R852= (on ENST00000403359 / NM_001190274.2; = p.R768= on NM_025133.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- FIGN | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- GRIA2 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.1259C>A p.P420Q | Missense Mutation (SNP) | VAF 22/756 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- KLHL4 | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- LATS1 | c.1009A>C p.K337Q | Missense Mutation (SNP) | VAF 239/650 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LCE1D | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 19/204 reads (9%) | PolyPhen benign (0.017); called by muse, mutect2
- MUC16 | c.18226C>A p.P6076T | Missense Mutation (SNP) | VAF 173/541 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MYORG | c.1945C>G p.R649G | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NDST1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- RAB11FIP2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 59/412 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS4 | c.514del p.V172Sfs*27 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | called by mutect2, pindel, varscan2
- RNASE6 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 126/348 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SDCCAG8 | c.344T>G p.M115R | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.093); called by muse, mutect2
- SEPSECS | c.212_214del p.G71del | In Frame Del (DEL) | VAF 102/296 reads (34%) | called by pindel, varscan2
- SEZ6L | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- SMAD2 | c.236+1G>A p.X79_splice | Splice Site (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- SMAD3 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 21/545 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- STRC | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); called by muse, mutect2
- UBXN7 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- C4orf54 | c.156C>T p.A52= | Silent (SNP) | VAF 120/346 reads (35%) | catalogued as COSV72766832; called by muse, mutect2, varscan2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 38/343 reads (11%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- CDC25B | c.747C>T p.S249= (on ENST00000245960 / NM_021873.3; = p.S235= on NM_004358.4) | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as COSV55658113; called by muse, mutect2, varscan2
- CYP27B1 | c.237C>T p.S79= | Silent (SNP) | VAF 169/471 reads (36%) | catalogued as rs1216687925; called by muse, mutect2, varscan2
- DNMBP | c.1131C>T p.D377= | Silent (SNP) | VAF 23/362 reads (6%) | catalogued as rs560503880, COSV100143717, COSV60627410; called by muse, mutect2
- DUSP22 | c.93G>A p.V31= | Silent (SNP) | VAF 10/257 reads (4%) | called by muse, mutect2
- ELP6 | c.699G>A p.S233= | Silent (SNP) | VAF 27/290 reads (9%) | catalogued as rs763976026, COSV56132227; called by muse, mutect2
- FBN3 | c.4125C>T p.N1375= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs184683769, COSV54466758; called by muse, mutect2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 116/292 reads (40%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2, varscan2
- HEATR4 | c.2577C>T p.N859= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs777014455; called by muse, mutect2
- KCNN2 | c.798C>G p.L266= (on ENST00000264773; = p.L478= on NM_021614.4) | Silent (SNP) | VAF 186/445 reads (42%) | called by muse, mutect2, varscan2
- LAMA2 | c.1599C>A p.T533= | Silent (SNP) | VAF 129/329 reads (39%) | called by muse, mutect2, varscan2
- LRWD1 | c.1563C>A p.I521= | Silent (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- NLRP7 | c.543C>T p.G181= | Silent (SNP) | VAF 178/436 reads (41%) | catalogued as rs752629343, COSV60175839; called by muse, mutect2, varscan2
- NRG3 | c.423C>T p.S141= | Silent (SNP) | VAF 96/285 reads (34%) | catalogued as rs762036310, COSV64557583; called by muse, mutect2, varscan2
- PATJ | c.4881G>A p.Q1627= | Silent (SNP) | VAF 13/388 reads (3%) | called by muse, mutect2
- PCDH19 | c.2703C>A p.G901= (on ENST00000373034 / NM_001184880.2; = p.G853= on NM_020766.3) | Silent (SNP) | VAF 302/757 reads (40%) | catalogued as rs748948987; called by muse, mutect2, varscan2
- PMEPA1 | c.699C>T p.S233= | Silent (SNP) | VAF 123/336 reads (37%) | catalogued as rs531021898, COSV99671749; called by muse, mutect2, varscan2
- PROKR1 | c.618C>A p.L206= | Silent (SNP) | VAF 62/526 reads (12%) | catalogued as COSV100375453; called by muse, mutect2, varscan2
- PTPN13 | c.4926G>A p.Q1642= (on ENST00000411767 / NM_080683.3; = p.Q1623= on NM_006264.3) | Silent (SNP) | VAF 109/308 reads (35%) | called by muse, mutect2, varscan2
- SCAND1 | c.117G>A p.S39= | Silent (SNP) | VAF 208/499 reads (42%) | catalogued as rs1056803764; called by muse, mutect2, varscan2
- SCN1B | c.376C>T p.L126= | Silent (SNP) | VAF 199/497 reads (40%) | called by muse, mutect2, varscan2
- SLC35A2 | c.30C>T p.T10= | Silent (SNP) | VAF 164/462 reads (35%) | catalogued as rs373480204; called by muse, mutect2, varscan2
- TBX18 | c.165C>T p.C55= | Silent (SNP) | VAF 22/688 reads (3%) | called by muse, mutect2
- TMEM63A | c.1896G>A p.A632= | Silent (SNP) | VAF 130/296 reads (44%) | catalogued as rs770289236; called by muse, mutect2, varscan2
- TMTC1 | c.1179G>A p.P393= (on ENST00000539277 / NM_001193451.2; = p.P285= on NM_175861.3) | Silent (SNP) | VAF 139/398 reads (35%) | catalogued as rs372059579; called by muse, mutect2, varscan2
- ZFHX4 | c.5238G>A p.T1746= | Silent (SNP) | VAF 114/279 reads (41%) | catalogued as COSV50651121, COSV51492261; called by muse, mutect2, varscan2
- ZFP36L2 | c.36C>A p.V12= | Silent (SNP) | VAF 215/468 reads (46%) | called by muse, mutect2, varscan2
- ZNF676 | c.1560G>A p.T520= (on ENST00000650058; = p.T488= on NM_001001411.3) | Silent (SNP) | VAF 152/456 reads (33%) | catalogued as rs775446763, COSV101236103; called by muse, mutect2, varscan2
- ZNRF4 | c.57C>T p.A19= | Silent (SNP) | VAF 80/265 reads (30%) | catalogued as rs754163190; called by muse, mutect2, varscan2
- AC005670.2 | chr17:47049864 T>C | 3'Flank (SNP) | VAF 87/782 reads (11%) | catalogued as rs781345103; called by muse, mutect2, varscan2
- B3GAT1 | c.-22G>A | 5'UTR (SNP) | VAF 89/254 reads (35%) | catalogued as rs369890603; called by muse, mutect2, varscan2
- C19orf12 | chr19:29699079 A>G | 3'Flank (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- CLCN6 | c.2529+186A>C | Intron (SNP) | VAF 165/243 reads (68%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2762T>C | 3'UTR (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- DOK1 | c.-1C>A | 5'UTR (SNP) | VAF 120/304 reads (39%) | called by muse, varscan2
- GRID2 | chr4:92300870 G>C | 5'Flank (SNP) | VAF 73/183 reads (40%) | called by muse, mutect2, varscan2
- HNRNPM | c.-9G>A | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4488T>C | Intron (SNP) | VAF 42/1028 reads (4%) | called by muse, mutect2
- RPL22L1 | c.103-36C>T | Intron (SNP) | VAF 9/176 reads (5%) | catalogued as rs1328673301; called by muse, mutect2
- SHROOM2 | chrX:9786268 G>C | 5'Flank (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- YWHAH | c.-60G>A | 5'UTR (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
